Surgical pathology report (de-identified scan), TCGA case TCGA-19-0955, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-0955-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Name:
Accession #:
Date of Procedure
Date Received:

FINAL DIAGNOSIS

A. RIGHT PARIETAL OCCIPITAL LOBE BRAIN, TUMOR, REMOVAL:
-- GLIOSARCOMA (GLIOBLASTOMA MULTIFORME WITH FOCAL SPINDLE CELL DIFFERENTIATION, WHO GRADE IV).

Note: Reticulin histochemistry and immunohistochemical staining for neurofilaments and endothelial antigens support the diagnosis. Coagulative tumor necrosis is prominent. There is mild microvascular proliferation. Leptomeningeal invasion is prominent.

B. RIGHT PARIETAL OCCIPITAL DURA, BIOPSY:
-- DURA MATER WITH ADHERENT MALIGNANT GLIOMA.

One or more of the reagents used to perform assays on this specimen MAY have contained components considered to be analyte specific reagents (ASR's). ASR's have not been cleared or approved by the U.S. Food and Drug Administration. These assays were developed and their performance characteristics determined by the Department of Pathology at [REDACTED]. The assays were performed with appropriate positive and negative controls.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies

Intraoperative Consult Diagnosis

A. Microscopic: Gliosarcoma.

Clinical History:

Right parietal occipital brain tumor

Specimens Submitted As:

A: RIGHT PARIETAL OCCIPITAL BRAIN TUMOR
B: RIGHT DURA WITH TUMOR

Gross Description:

A: Received fresh, for intraoperative consultation, labelled with the patient's name and number, is a single fragment of irregular, tan-brown mass measuring 5.0 x 3.5 x 3.0 cm in greatest dimension. A smooth surface is noted and an irregular surface is noted. The specimen is sectioned revealing a necrotic center with rimming by tan-gray tissue. Touch imprints are made and a portion of the specimen is frozen. A portion of the specimen is given to tissue procurement. Representative sections are submitted in five cassettes.

B: Received in formalin, labeled with the patient's name and number, are two opaque white to light tan triangular soft tissue fragments measuring 2.9 x 2.8 x 0.1 cm and 3.2 x 2.1 x 0.1 cm. The fragments are serially sectioned. Also received is one tan to dark red irregular soft tissue fragment measuring 0.7 x 0.1 x 0.1 cm. Submitted entirely in three cassettes.

[page 2 of 2]
Summary of Cassettes:

Specimen	Label	Site
A	1	frozen section
	2-5	representative sections of tumor
B	1, 2	traingular fragments
	3	remaining tissue

Source: NCI Genomic Data Commons file 558bdafd-4eb4-40db-8ead-f1edb104a03c (TCGA-19-0955.2C009AC4-3F16-43D8-AD3F-5B6FECC9F49C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).